Gene-level copy-number profile of tumor specimen TARGET-20-PATAST-04A from TARGET case TARGET-20-PATAST, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.2 years (5,926 days).
Specimen TARGET-20-PATAST-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-AML.9565d37f-cb9e-5654-ade1-977e891adb4c.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-20-PATAST-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 391 have no estimate.
https://portal.gdc.cancer.gov/files/c3b4a72d-89f7-4ad5-ad3c-775ceeaaad58

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,385; copy number 1: 818; copy number 2: 56,779; copy number 3: 24; copy number 4: 143; copy number 5: 83.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,540,049–75,590,649, 3 genes: AC133041.1, RPS3AP15, AC108724.1.
- chr12:9,480,608–9,576,275, 2 genes (within-gene range 0–2): AC092821.1, AC092821.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 83 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–19,957,996, 83 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 816. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
